Somatic mutation profile of tumor specimen MP2PRT-PAUDIE-TMP1-A (aliquot MP2PRT-PAUDIE-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PAUDIE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.9 years (2,166 days).
Specimen MP2PRT-PAUDIE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3b2e157-bcb0-4266-b391-44d47c245a02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUDIE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUDIE-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/546f2646-cbe6-46ce-b55b-6caac05a38db

The open-access MAF lists 143 somatic variants for this specimen: 97 protein-altering or splice-affecting, 41 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 41, Nonsense Mutation 8, Frame Shift Ins 3, 5'UTR 2, 5'Flank 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALKBH3 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 42/335 reads (13%) | catalogued as COSV100236571; called by muse, mutect2, varscan2
- ATL2 | c.101C>G p.S34W | Missense Mutation (SNP) | VAF 23/617 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as COSV60054608; called by muse, mutect2
- ATXN2L | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 26/435 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57365771; called by muse, mutect2
- BNC1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 66/510 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61756516; called by muse, mutect2, varscan2
- BTNL9 | c.1434C>G p.F478L | Missense Mutation (SNP) | VAF 43/648 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59799334; called by muse, mutect2
- CAMSAP3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 67/498 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.646); catalogued as rs748688250; called by muse, mutect2, varscan2
- CCDC78 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.431); catalogued as rs761094524; called by muse, mutect2, varscan2
- CETN3 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as rs1034508226; called by muse, mutect2, varscan2
- CFP | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 104/314 reads (33%) | catalogued as COSV55949636, COSV55949827; called by muse, mutect2, varscan2
- DCAF4 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 31/365 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs537123814, COSV62319268; called by muse, mutect2
- DNMT1 | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755865204; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF4G1 | c.2111C>G p.S704C (on ENST00000346169 / NM_198241.3; = p.S509C on NM_004953.5) | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs141054452; called by muse, mutect2
- EMB | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 31/166 reads (19%) | catalogued as rs762962474; called by muse, mutect2, varscan2
- EPB41L3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 303/690 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV59469899; called by muse, mutect2, varscan2
- FAT3 | c.13045G>A p.D4349N | Missense Mutation (SNP) | VAF 107/292 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377319957; called by muse, mutect2, varscan2
- FBXO15 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54045670; called by muse, mutect2, varscan2
- FMN2 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 84/888 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV100142594; called by muse, mutect2
- HEXA | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51506617; called by muse, mutect2
- IKZF1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs1184423158, COSV58786188, COSV58792045; called by muse, mutect2
- LDOC1 | c.249C>A p.C83* | Nonsense Mutation (SNP) | VAF 70/741 reads (9%) | catalogued as COSV65159638; called by muse, mutect2
- LIN28B | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 120/410 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.886); catalogued as COSV100558655; called by muse, mutect2, varscan2
- LRRC52 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 62/544 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1331070925, COSV54233033, COSV54234146; called by muse, mutect2, varscan2
- MAN2A1 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 20/524 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV99811852; called by muse, mutect2
- MAPK4 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 90/732 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV68541409; called by muse, mutect2, varscan2
- MCAT | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1309020719; called by muse, mutect2
- MDN1 | c.10906C>G p.R3636G | Missense Mutation (SNP) | VAF 49/458 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs749987769; called by muse, mutect2, varscan2
- MXRA5 | c.2353G>A p.D785N | Missense Mutation (SNP) | VAF 191/562 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as rs760375645, COSV54228446; called by muse, varscan2
- NELL2 | c.1147C>T p.H383Y | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs1197781747, COSV61568549, COSV61583526; called by muse, mutect2, varscan2
- POU2AF1 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 123/437 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV67577090; called by muse, mutect2, varscan2
- PPP2R2B | c.848C>T p.S283L (on ENST00000394409; = p.S349L on NM_181674.2) | Missense Mutation (SNP) | VAF 121/376 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770649547, COSV60761342; called by muse, mutect2, varscan2
- PRKCB | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 168/394 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs775901586; called by muse, mutect2, varscan2
- RFXANK | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1481704512; called by muse, mutect2, varscan2
- RIMS1 | c.4741C>G p.L1581V | Missense Mutation (SNP) | VAF 81/255 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99330402; called by muse, mutect2, varscan2
- SERPINA4 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 152/399 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs369829056; called by muse, mutect2, varscan2
- SHC3 | c.341C>G p.S114W | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV65441293; called by muse, mutect2, varscan2
- SI | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 30/142 reads (21%) | catalogued as rs754468827; called by muse, mutect2, varscan2
- SYT6 | c.546G>C p.Q182H (on ENST00000610222 / NM_001366225.1; = p.Q97H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as rs371848111; called by muse, mutect2, varscan2
- TFCP2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.794); catalogued as COSV56933524, COSV56934480; called by muse, mutect2, varscan2
- THSD7A | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 30/600 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs767811878, COSV70260472; called by muse, mutect2
- TONSL | c.1535G>A p.G512D | Missense Mutation (SNP) | VAF 178/539 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs539239669; called by muse, mutect2, varscan2
- UCKL1 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 37/339 reads (11%) | catalogued as rs761010214; called by muse, mutect2, varscan2
- VCAN | c.3917C>T p.A1306V | Missense Mutation (SNP) | VAF 114/410 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as rs749496810; called by muse, mutect2, varscan2
- ADGRL3 | c.1384C>A p.L462M (on ENST00000506720 / NM_001322402.2; = p.L394M on NM_015236.6) | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.805); called by muse, mutect2
- AKAP8 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 58/570 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ALDOA | c.265G>A p.E89K (on ENST00000642816 / NM_001243177.4; = p.E35K on NM_184041.5) | Missense Mutation (SNP) | VAF 23/391 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, mutect2
- ALDOA | c.324G>C p.E108D (on ENST00000642816 / NM_001243177.4; = p.E54D on NM_184041.5) | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2
- ASB15 | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.074); called by muse, mutect2
- BIRC6 | c.3929C>T p.S1310L | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- COL4A5 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 122/456 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD1 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 41/445 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.336); called by muse, mutect2
- DCDC1 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); called by muse, mutect2
- DECR2 | c.743G>T p.S248I | Missense Mutation (SNP) | VAF 68/632 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- DEFB108B | c.42G>A p.M14I | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNAAF6 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 84/308 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- ERCC6L | c.3083C>T p.S1028L | Missense Mutation (SNP) | VAF 54/498 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ESAM | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 176/565 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM155A | c.1140G>C p.R380S | Missense Mutation (SNP) | VAF 14/437 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GAD2 | c.913G>C p.D305H | Missense Mutation (SNP) | VAF 14/465 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GIGYF2 | c.2656G>C p.E886Q | Missense Mutation (SNP) | VAF 38/326 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.398); called by muse, varscan2
- GRIN2D | c.2816C>T p.S939L | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- GRXCR2 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 43/506 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- H1-2 | c.84dup p.G29Wfs*6 | Frame Shift Ins (INS) | VAF 162/433 reads (37%) | called by mutect2, pindel, varscan2
- HECW1 | c.4075G>A p.D1359N | Missense Mutation (SNP) | VAF 46/488 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2
- HSPG2 | c.10796C>T p.S3599L | Missense Mutation (SNP) | VAF 139/305 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV3-66 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 15/313 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IGHV4-59 | c.346_347insCCCTCGA p.R116Tfs*? | Frame Shift Ins (INS) | VAF 35/63 reads (56%) | called by mutect2, pindel, varscan2
- IGHV4-61 | c.352_353insCCCTCGA p.R118Tfs*? | Frame Shift Ins (INS) | VAF 9/18 reads (50%) | called by mutect2, pindel
- ITSN1 | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.731); called by muse, mutect2
- KLK5 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 134/380 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRBA1 | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 116/450 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LUC7L2 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.842); called by muse, mutect2
- LUM | c.879C>G p.S293R | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- MCAT | c.121G>C p.D41H | Missense Mutation (SNP) | VAF 80/720 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- MCF2L | c.1999G>A p.A667T (on ENST00000375608; = p.A635T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/306 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MCF2L | c.2374G>A p.E792K (on ENST00000375608; = p.E760K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/318 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- MDN1 | c.8044G>A p.E2682K | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.119); called by muse, mutect2
- MXRA5 | c.3265G>C p.E1089Q | Missense Mutation (SNP) | VAF 168/581 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- N4BP2 | c.3217G>A p.D1073N | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- NCAN | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 122/447 reads (27%) | called by muse, mutect2, varscan2
- NOP14 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 74/599 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PACSIN2 | c.1221C>G p.F407L | Missense Mutation (SNP) | VAF 132/409 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- PCDH15 | c.4956C>A p.N1652K (on ENST00000644397 / NM_001354429.2; = p.N1594K on NM_001142771.2) | Missense Mutation (SNP) | VAF 64/489 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCDHGB4 | c.1829G>C p.S610T | Missense Mutation (SNP) | VAF 78/621 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PRKCB | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 118/255 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- SCGN | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SECISBP2L | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 99/375 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SIGLEC5 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SPOCK1 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 55/391 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ST14 | c.2414C>T p.S805F | Missense Mutation (SNP) | VAF 24/569 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYNPO2 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 123/405 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SYNPO2 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 58/468 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TEX13C | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 142/405 reads (35%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TMEM35B | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 18/365 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.019); called by muse, mutect2
- TRIM61 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 50/605 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- UHRF1BP1L | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 41/460 reads (9%) | called by muse, mutect2
- ZFP37 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.011); called by muse, mutect2
- ZNF227 | c.402G>C p.K134N | Missense Mutation (SNP) | VAF 77/275 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALDH3B1 | c.171C>T p.F57= | Silent (SNP) | VAF 142/312 reads (46%) | catalogued as rs188211650; called by muse, mutect2
- ALG6 | c.1446C>T p.F482= | Silent (SNP) | VAF 68/254 reads (27%) | called by muse, mutect2, varscan2
- ANKRD36C | c.3645C>G p.V1215= | Silent (SNP) | VAF 27/176 reads (15%) | called by muse, mutect2, varscan2
- CCND2 | c.111C>T p.Y37= | Silent (SNP) | VAF 39/790 reads (5%) | catalogued as rs768686427; called by muse, mutect2
- CD5 | c.408G>A p.Q136= | Silent (SNP) | VAF 19/516 reads (4%) | called by muse, mutect2
- CGNL1 | c.2224C>T p.L742= | Silent (SNP) | VAF 28/294 reads (10%) | catalogued as rs1318879179, COSV55577187; called by muse, mutect2, varscan2
- CHMP1B | c.586C>A p.R196= | Silent (SNP) | VAF 91/291 reads (31%) | called by muse, mutect2, varscan2
- DIP2A | c.3327C>G p.L1109= | Silent (SNP) | VAF 114/349 reads (33%) | called by muse, mutect2, varscan2
- EGFL8 | c.255G>C p.V85= | Silent (SNP) | VAF 102/444 reads (23%) | called by muse, mutect2, varscan2
- ELF4 | c.897C>T p.V299= | Silent (SNP) | VAF 97/683 reads (14%) | catalogued as rs1458250058; called by muse, mutect2, varscan2
- FANCE | c.1488G>C p.V496= | Silent (SNP) | VAF 82/301 reads (27%) | called by muse, mutect2, varscan2
- FAT2 | c.432G>A p.L144= | Silent (SNP) | VAF 57/441 reads (13%) | catalogued as rs746064399; called by muse, mutect2, varscan2
- FLT1 | c.2931G>C p.L977= | Silent (SNP) | VAF 37/322 reads (11%) | catalogued as COSV99030674; called by muse, mutect2, varscan2
- GPR22 | c.753G>A p.K251= | Silent (SNP) | VAF 80/298 reads (27%) | catalogued as COSV51753403; called by muse, mutect2, varscan2
- HAND1 | c.84C>T p.L28= | Silent (SNP) | VAF 188/579 reads (32%) | catalogued as COSV50562539; called by muse, mutect2, varscan2
- HSPG2 | c.11313G>A p.L3771= | Silent (SNP) | VAF 174/429 reads (41%) | called by muse, mutect2, varscan2
- ITGB3 | c.1332C>T p.P444= | Silent (SNP) | VAF 43/388 reads (11%) | catalogued as rs765488914, COSV101457584; called by muse, mutect2, varscan2
- KRBA1 | c.579G>A p.E193= | Silent (SNP) | VAF 70/256 reads (27%) | called by muse, mutect2, varscan2
- KREMEN2 | c.780C>T p.F260= | Silent (SNP) | VAF 48/826 reads (6%) | called by muse, mutect2
- LDHC | c.540C>T p.V180= | Silent (SNP) | VAF 46/332 reads (14%) | catalogued as rs1404743287, COSV99772377; called by muse, mutect2, varscan2
- LHFPL4 | c.177C>T p.F59= | Silent (SNP) | VAF 69/580 reads (12%) | called by muse, mutect2, varscan2
- LRRK2 | c.423C>T p.L141= | Silent (SNP) | VAF 26/274 reads (9%) | called by muse, mutect2
- NCKAP1L | c.2472G>A p.Q824= | Silent (SNP) | VAF 28/238 reads (12%) | called by muse, mutect2, varscan2
- NINL | c.2244G>A p.L748= | Silent (SNP) | VAF 294/689 reads (43%) | catalogued as rs749816276; called by muse, mutect2, varscan2
- PES1 | c.21G>A p.K7= | Silent (SNP) | VAF 123/418 reads (29%) | catalogued as rs371309211; called by muse, mutect2, varscan2
- PLXNA4 | c.5028C>A p.I1676= | Silent (SNP) | VAF 116/383 reads (30%) | called by muse, mutect2, varscan2
- PTH2R | c.1203C>T p.F401= | Silent (SNP) | VAF 98/396 reads (25%) | catalogued as rs753457723; called by muse, mutect2, varscan2
- RAP2A | c.483G>A p.V161= | Silent (SNP) | VAF 48/435 reads (11%) | called by muse, mutect2, varscan2
- SLC25A43 | c.648G>A p.Q216= | Silent (SNP) | VAF 46/537 reads (9%) | catalogued as COSV99474809; called by muse, mutect2
- SPANXN1 | c.114G>A p.P38= | Silent (SNP) | VAF 44/384 reads (11%) | catalogued as rs148223407; called by muse, mutect2, varscan2
- SPPL2B | c.549G>A p.V183= | Silent (SNP) | VAF 183/392 reads (47%) | called by muse, mutect2, varscan2
- SPRN | c.279G>A p.A93= | Silent (SNP) | VAF 48/409 reads (12%) | catalogued as rs1177242651; called by muse, mutect2, varscan2
- STARD8 | c.408G>C p.L136= | Silent (SNP) | VAF 46/852 reads (5%) | catalogued as COSV52930361; called by muse, mutect2
- TAMM41 | c.936G>A p.L312= | Silent (SNP) | VAF 34/388 reads (9%) | catalogued as rs748840863, COSV56071387; called by muse, mutect2
- TBC1D25 | c.1539C>G p.L513= | Silent (SNP) | VAF 28/863 reads (3%) | catalogued as rs1226287323; called by muse, mutect2
- TMEM63A | c.894C>T p.L298= | Silent (SNP) | VAF 123/412 reads (30%) | catalogued as rs540935026, COSV64764022; called by muse, mutect2, varscan2
- TTC13 | c.1132C>T p.L378= | Silent (SNP) | VAF 23/238 reads (10%) | called by muse, mutect2, varscan2
- ZAN | c.1191C>T p.L397= | Silent (SNP) | VAF 34/504 reads (7%) | catalogued as rs771649484; called by muse, mutect2
- ZFHX3 | c.3558G>C p.L1186= | Silent (SNP) | VAF 12/382 reads (3%) | called by muse, mutect2
- ZFHX4 | c.603C>T p.L201= | Silent (SNP) | VAF 19/368 reads (5%) | catalogued as rs954096599, COSV99266531; called by muse, mutect2
- ZRANB3 | c.2262G>A p.Q754= | Silent (SNP) | VAF 12/249 reads (5%) | catalogued as rs1452351711; called by muse, mutect2
- C2orf16 | chr2:27572280 C>G | 5'Flank (SNP) | VAF 20/450 reads (4%) | called by muse, mutect2
- IGKV2D-24 | chr2:90005629 ins CCCTC | 3'Flank (INS) | VAF 60/94 reads (64%) | called by mutect2, varscan2
- NKAPD1 | c.-412C>T | 5'UTR (SNP) | VAF 24/314 reads (8%) | catalogued as rs1442564565; called by muse, mutect2
- RASGEF1B | c.255+38G>A | Intron (SNP) | VAF 141/348 reads (41%) | catalogued as rs559579302, COSV72543838; called by muse, mutect2, varscan2
- ZBTB18 | c.-6G>C | 5'UTR (SNP) | VAF 27/277 reads (10%) | catalogued as rs1302570409; called by muse, mutect2
